Gene-level copy-number profile of tumor specimen TCGA-KL-8341-01A from TCGA case TCGA-KL-8341, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.2 years (15,045 days).
Specimen TCGA-KL-8341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.ccbe0104-89ff-4494-8183-26146439d4fa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KL-8341-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d461ecfe-f31f-4cab-838f-b33a73c23e59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 72; copy number 2: 25,329; copy number 3: 9,344; copy number 4: 22,311; copy number 5: 1,578; copy number 6: 463; copy number 7: 225; copy number 8: 66; copy number 9: 96; copy number 10: 24; copy number 11: 46; copy number 13: 53; copy number 14: 4; copy number 15: 32; copy number 19: 102.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KL-8341-01A-11D-2308-01): tumor purity 0.96, ploidy 1.61, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,689 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:26,614,261–28,349,050, 22 genes, copy number 5–6 (within-gene range 3–6): AC099754.1, LRRC3B, NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981, LINC01967, CMC1, AZI2.
- chr3:30,292,548–30,699,576, 8 genes, copy number 6: AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2.
- chr3:31,161,704–49,429,326, 439 genes, copy number 6–9 (broad region; genes not listed).
- chr3:124,723,788–124,953,819, 10 genes, copy number 5: AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13.
- chr5:58,198–693,352, 27 genes, copy number 7 (within-gene range 3–7): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:1,173,141–1,295,068, 5 genes, copy number 9 (within-gene range 2–9): CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:31,400,497–32,121,941, 22 genes, copy number 5 (within-gene range 3–5): DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1.
- chr7:63,011,463–139,544,985, 1,434 genes, copy number 5–8 (broad region; genes not listed).
- chr7:150,944,961–151,440,813, 30 genes, copy number 5 (within-gene range 2–5): KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907.
- chr8:50,859,530–52,745,843, 20 genes, copy number 10 (within-gene range 4–10): AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1.
- chr8:53,225,724–53,390,872, 2 genes, copy number 6: OPRK1, AC131902.1.
- chr8:53,394,215–53,394,795, 1 gene, copy number 6: AC131902.2.
- chr8:76,265,543–80,585,773, 59 genes, copy number 5–6: RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P.
- chr8:94,352,923–104,484,465, 225 genes, copy number 7–19 (broad region; genes not listed).
- chr8:105,546,089–111,757,710, 64 genes, copy number 11–13 (broad region; genes not listed).
- chr8:115,408,496–115,809,673, 2 genes, copy number 11: TRPS1, AF178030.1.
- chr8:116,022,686–116,022,779, 1 gene, copy number 11: RNA5SP276.
- chr12:3,077,355–3,366,122, 8 genes, copy number 5 (within-gene range 3–5): TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827.
- chr15:47,184,101–47,774,228, 1 gene, copy number 5 (within-gene range 3–5): SEMA6D.
- chr15:47,525,169–50,418,692, 62 genes, copy number 5–7 (broad region; genes not listed).
- chr15:51,056,598–51,105,276, 2 genes, copy number 8: TNFAIP8L3, AC073964.1.
- chr15:53,513,741–56,245,082, 35 genes, copy number 6–7 (within-gene range 3–7): WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74, AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2, PIGBOS1, PIGB, CCPG1, AC018926.1, AC018926.3, DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1.
- chr15:56,248,787–56,274,636, 2 genes, copy number 7: AC068726.1, RNU6-1287P.
- chr15:59,372,693–59,523,555, 1 gene, copy number 9 (within-gene range 2–9): FAM81A.
- chr15:59,406,963–67,873,866, 207 genes, copy number 6–15 (within-gene range 3–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 72. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
